Somatic mutation profile of tumor specimen TCGA-A6-2675-01A (aliquot TCGA-A6-2675-01A-02D-1719-10) from TCGA case TCGA-A6-2675, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 78.9 years (28,813 days).
Specimen TCGA-A6-2675-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8582895-4132-425d-8cc7-3e13f2dd89cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2675-10A (Blood Derived Normal), aliquot TCGA-A6-2675-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0238e5a-c21b-459d-93ca-7c40e10dd621

The open-access MAF lists 104 somatic variants for this specimen: 69 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 34, Nonsense Mutation 4, Frame Shift Del 2, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 40/199 reads (20%) | catalogued as rs587779780, CD042580, CM920031, COSV57322404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 17/117 reads (15%) | catalogued as rs863223852, CM063204, COSV55443474; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 47/131 reads (36%) | hotspot (GDC flag); catalogued as rs1567551854, COSV52678088, COSV52771688, COSV53175941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.1409C>T p.T470M (on ENST00000614293; = p.T440M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99686638; called by muse, mutect2, varscan2
- ABCC8 | c.3682G>A p.E1228K | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs758995284, COSV56858022; called by muse, mutect2, varscan2
- ACACB | c.787G>C p.V263L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754475585, COSV58147039; called by muse, mutect2, varscan2
- ATP7A | c.3302A>G p.D1101G | Missense Mutation (SNP) | VAF 63/94 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58454168; called by muse, mutect2, varscan2
- C3orf84 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs772908960, COSV100234033; called by muse, mutect2, varscan2
- CC2D2A | c.1818G>C p.E606D | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.221); catalogued as COSV67505711; called by muse, mutect2, varscan2
- CEP350 | c.6407C>A p.P2136H | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs867952059, COSV100854206; called by muse, mutect2, varscan2
- CFAP69 | c.1984A>G p.I662V | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.741); catalogued as COSV60188587; called by muse, mutect2, varscan2
- CLIP3 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs757632653, COSV53324606; called by muse, mutect2, varscan2
- CNN1 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as rs748140771, COSV52955266, COSV52956274; called by muse, mutect2, varscan2
- CNTN5 | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199670730, COSV54327730, COSV99671445; called by muse, mutect2, varscan2
- CORO7 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.657); catalogued as rs1279864756, COSV52034098; called by muse, mutect2, varscan2
- DCC | c.3319G>T p.G1107C | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101472176; called by muse, mutect2, varscan2
- DNAH5 | c.10859G>A p.R3620Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs547014532, COSV54205387, COSV54209411; called by muse, mutect2, varscan2
- GALNT18 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99923460; called by muse, mutect2
- JCAD | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.648); catalogued as rs749382590, COSV64761742; called by muse, mutect2, varscan2
- KRT12 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as rs146332400; called by muse, mutect2, varscan2
- KRT4 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs375246611; called by muse, mutect2, varscan2
- KRTAP12-1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782316833, COSV100551354; called by muse, mutect2, varscan2
- LAMC3 | c.4093G>A p.V1365I | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs148481163; called by muse, mutect2, varscan2
- LUC7L2 | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99692621; called by muse, mutect2, varscan2
- MACC1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs143659230, COSV60546582, COSV60547340; called by muse, mutect2, varscan2
- MEFV | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1206762845, COSV54824487, COSV54825840; called by muse, mutect2, varscan2
- MEP1A | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57922618; called by muse, mutect2, varscan2
- MMP1 | c.484T>C p.S162P | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100187732; called by muse, mutect2, varscan2
- MMP26 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs764121875, COSV56173211; called by muse, mutect2
- MSRB3 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267603630, COSV57589447; called by muse, mutect2, varscan2
- MYH9 | c.2116C>T p.Q706* | Nonsense Mutation (SNP) | VAF 13/112 reads (12%) | catalogued as CM066584, COSV53382079; called by muse, mutect2, varscan2
- NEU1 | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.705); catalogued as COSV57669181; called by muse, mutect2, varscan2
- NMT2 | c.364T>A p.W122R | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65383312; called by muse, mutect2, varscan2
- NMT2 | c.363T>A p.F121L | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65383318; called by muse, mutect2, varscan2
- NMUR2 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54922987; called by muse, mutect2, varscan2
- NPFFR1 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs760246373, COSV53334963; called by muse, varscan2
- NPSR1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 78/154 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1351919281, COSV62207905; called by muse, mutect2, varscan2
- OR2T4 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 102/583 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs151201153, COSV63543315; called by muse, mutect2, varscan2
- OR4C46 | c.662G>A p.C221Y | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as COSV60221269; called by muse, mutect2, varscan2
- P2RY4 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 71/109 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65736202; called by muse, mutect2, varscan2
- PCDH15 | c.4996G>A p.A1666T (on ENST00000644397 / NM_001354429.2; = p.A1608T on NM_001142771.2) | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV100902198; called by muse, mutect2, varscan2
- PIH1D1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV51807647, COSV99220978; called by muse, mutect2
- PIK3C2G | c.4130T>C p.I1377T (on ENST00000676171; = p.I1336T on NM_004570.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV99848658; called by muse, mutect2, varscan2
- RBP4 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383758574, COSV65159696; called by muse, mutect2, varscan2
- RFX7 | c.3290C>A p.T1097N (on ENST00000559447 / NM_001368074.1; = p.T1194N on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV57968984; called by muse, mutect2, varscan2
- RGS11 | c.591C>T p.P197= (on ENST00000397770 / NM_183337.3; = p.P176= on NM_003834.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 21/62 reads (34%) | catalogued as rs771119169, COSV51454138; called by muse, mutect2, varscan2
- RSPO4 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs201621545; called by muse, mutect2, varscan2
- SAAL1 | c.631T>A p.F211I | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV55517347; called by muse, mutect2
- SCN10A | c.2465C>T p.A822V | Missense Mutation (SNP) | VAF 70/384 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs747839312, COSV71860730; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC45A2 | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1490565269, COSV99672172; called by muse, mutect2, varscan2
- SORBS2 | c.1810G>T p.V604L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as COSV53015458; called by muse, mutect2, varscan2
- SPATA5 | c.1041A>T p.Q347H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.289); catalogued as COSV56784793; called by muse, mutect2, varscan2
- SPG11 | c.3214G>T p.V1072L | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV56002316; called by muse, mutect2, varscan2
- SVIL | c.4084A>G p.K1362E (on ENST00000355867 / NM_021738.3; = p.K936E on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV100880751; called by muse, varscan2
- SYT4 | c.1110_1111del p.I370Mfs*3 | Frame Shift Del (DEL) | VAF 77/246 reads (31%) | catalogued as COSV54904281; called by mutect2, pindel, varscan2
- TDG | c.253T>C p.S85P | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.216); catalogued as COSV57168692; called by muse, mutect2, varscan2
- THYN1 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs777723936, COSV55539637; called by muse, mutect2, varscan2
- TMEM132B | c.2519A>C p.Q840P | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54770478; called by muse, mutect2, varscan2
- TMEM38B | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs533512053, COSV65966113; called by muse, mutect2, varscan2
- TMPRSS15 | c.2750C>T p.T917M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.339); catalogued as rs778496939, COSV53034807; called by muse, mutect2, varscan2
- TNN | c.3343C>T p.R1115W | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546877646, COSV53435922; called by muse, mutect2, varscan2
- TNNT3 | c.383G>A p.R128H (on ENST00000397301 / NM_001367846.1; = p.R117H on NM_006757.4) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1049172873, COSV53484734; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPC7 | c.2359C>T p.L787F | Missense Mutation (SNP) | VAF 68/230 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61458002; called by muse, mutect2, varscan2
- UBQLN4 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs374330338; called by muse, mutect2, varscan2
- ZNF398 | c.1760G>A p.R587H (on ENST00000475153 / NM_170686.3; = p.R416H on NM_020781.4) | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs747841925, COSV60066854; called by muse, mutect2, varscan2
- ZNF462 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs374076395; called by muse, mutect2, varscan2
- APC | c.606dup p.Q203Tfs*49 | Frame Shift Ins (INS) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- BCL9L | c.863del p.P288Rfs*4 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | called by mutect2, pindel*, varscan2
- SLC8B1 | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- A2ML1 | c.2487G>A p.S829= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs747051668, COSV55298213; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAMTS15 | c.1050C>T p.D350= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as rs765014170, COSV54509830; called by muse, mutect2, varscan2
- ANKRD12 | c.5152T>C p.L1718= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100040521; called by muse, varscan2
- ARFGEF2 | c.531C>T p.I177= | Silent (SNP) | VAF 58/347 reads (17%) | catalogued as COSV64215255; called by muse, mutect2, varscan2
- CAPN2 | c.495G>A p.L165= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV54340109; called by muse, mutect2, varscan2
- CASK | c.771G>A p.L257= | Silent (SNP) | VAF 47/84 reads (56%) | catalogued as COSV59363381, COSV59372005; called by muse, mutect2, varscan2
- CCER1 | c.108G>A p.S36= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs370822454, COSV62648740; called by muse, mutect2, varscan2
- CDH16 | c.2355G>A p.S785= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs771593914, COSV55339853; called by muse, mutect2, varscan2
- CERS6 | c.804C>G p.A268= | Silent (SNP) | VAF 75/236 reads (32%) | catalogued as COSV59835995; called by muse, mutect2, varscan2
- FAT4 | c.1455C>T p.S485= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV67894384; called by muse, mutect2, varscan2
- GPR174 | c.72G>C p.V24= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV52132945, COSV52134481; called by muse, mutect2, varscan2
- GUCY2D | c.1056C>T p.D352= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs763350634, COSV99643639; called by muse, mutect2, varscan2
- HEPN1 | c.42C>T p.G14= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs368280630, COSV53432572; called by muse, mutect2, varscan2
- KCTD8 | c.663C>T p.R221= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV63587629; called by muse, mutect2, varscan2
- LTBP2 | c.4041C>T p.N1347= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs772766355, COSV56207222; called by muse, mutect2, varscan2
- NIN | c.5415T>G p.S1805= (on ENST00000382041 / NM_182946.1; = p.S1092= on NM_016350.4) | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as rs1306135167, COSV55406783; called by muse, mutect2, varscan2
- NRK | c.171C>T p.N57= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs761109913, COSV54607111; called by muse, mutect2, varscan2
- PARP12 | c.819T>C p.D273= | Silent (SNP) | VAF 50/131 reads (38%) | catalogued as COSV54937271; called by muse, mutect2, varscan2
- PCDHA1 | c.2034G>A p.A678= | Silent (SNP) | VAF 16/298 reads (5%) | catalogued as rs562110007, COSV65375424; called by muse, mutect2
- PCSK4 | c.1431G>A p.S477= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs1568206677, COSV56301521; called by muse, mutect2, varscan2
- RHD | c.894T>C p.G298= | Silent (SNP) | VAF 7/164 reads (4%) | called by muse, mutect2
- ROCK2 | c.2922T>C p.T974= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV59965548; called by muse, mutect2, varscan2
- ROR1 | c.648T>C p.S216= | Silent (SNP) | VAF 19/208 reads (9%) | catalogued as COSV64293456; called by muse, mutect2
- SETBP1 | c.4707G>A p.P1569= | Silent (SNP) | VAF 10/177 reads (6%) | catalogued as COSV99951589; called by muse, mutect2
- SETD4 | c.408G>A p.A136= | Silent (SNP) | VAF 25/173 reads (14%) | catalogued as rs749415584, COSV100145510; called by muse, mutect2, varscan2
- SFMBT2 | c.2028C>T p.I676= | Silent (SNP) | VAF 61/184 reads (33%) | catalogued as rs371692681; called by muse, mutect2, varscan2
- SLC26A1 | c.786C>T p.C262= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs752471622, COSV56106628; called by muse, mutect2, varscan2
- SREBF2 | c.1221C>T p.I407= | Silent (SNP) | VAF 46/145 reads (32%) | catalogued as rs560473946, COSV100761310; called by muse, mutect2, varscan2
- TENM4 | c.5721C>T p.Y1907= | Silent (SNP) | VAF 75/311 reads (24%) | catalogued as rs768735704, COSV53625388; called by muse, mutect2, varscan2
- TUBB2B | c.612C>T p.N204= | Silent (SNP) | VAF 172/494 reads (35%) | catalogued as rs1250649134, COSV52534515; called by muse, varscan2
- UNC45B | c.2115C>A p.S705= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV99268049; called by muse, mutect2, varscan2
- ZFP69B | c.1074C>T p.T358= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs141195830; called by muse, mutect2, varscan2
- ZNF585B | c.2112G>A p.Q704= | Silent (SNP) | VAF 31/297 reads (10%) | catalogued as COSV100459237, COSV57217069; called by muse, mutect2, varscan2
- ZNF611 | c.561T>C p.A187= | Silent (SNP) | VAF 24/198 reads (12%) | catalogued as COSV60543430; called by muse, mutect2, varscan2
- TET2 | c.3409+53T>C | Intron (SNP) | VAF 27/163 reads (17%) | catalogued as COSV99480169; called by muse, mutect2, varscan2
